Somatic mutation profile of tumor specimen MMRF_2835_1_BM_CD138pos (aliquot MMRF_2835_1_BM_CD138pos_T1_KHS5U_L16565) from MMRF case MMRF_2835, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2835_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a6afd05-90ca-4049-95c5-254ad2b902e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2835_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2835_1_PB_WBC_C2_KHS5U_L16612; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a403e98b-acc6-4805-943f-c8d7350deb90

The open-access MAF lists 110 somatic variants for this specimen: 52 protein-altering or splice-affecting, 8 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 26, Intron 10, Silent 8, 5'UTR 8, Frame Shift Del 3, RNA 3, 5'Flank 2, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICC1 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1201634490; called by muse, mutect2, varscan2
- CHRNB2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749354110, COSV63808574; called by muse, mutect2
- CTNND2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs1278093121, COSV58898815; called by muse, mutect2, varscan2
- IGHV2-70 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs373048671; called by muse, varscan2
- IGHV2-70 | c.230A>C p.D77A | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs546960655; called by muse, varscan2
- IGHV2-70 | c.161G>C p.C54S | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- MEN1 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1254459338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK3 | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs779048286; called by muse, mutect2, varscan2
- NABP1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs368448206; called by muse, mutect2
- NCOA6 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs371905070; called by muse, mutect2, varscan2
- NLGN1 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV64330891; called by muse, mutect2, varscan2
- POLR1B | c.2209A>G p.I737V | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs564688801, COSV54499440; called by muse, mutect2, varscan2
- PTK7 | c.818C>A p.P273Q | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs151126990; called by muse, mutect2, varscan2
- PTPRB | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs769931378, COSV99718918; called by muse, mutect2, varscan2
- RAPGEF6 | c.3874C>T p.R1292W | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs770850083; called by muse, mutect2, varscan2
- SYCE1 | c.136+3C>G | Splice Region (SNP) | VAF 44/229 reads (19%) | catalogued as COSV100385787; called by muse, mutect2, varscan2
- TCF15 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1387181488; called by muse, mutect2, varscan2
- VCAN | c.1745T>C p.V582A | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1349401685; called by muse, mutect2
- VPS8 | c.2692C>T p.R898W (on ENST00000625842 / NM_001349294.1; = p.R896W on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as rs200766409; called by muse, mutect2, varscan2
- ZMIZ2 | c.2749_2752del p.F917Rfs*56 | Frame Shift Del (DEL) | VAF 107/415 reads (26%) | catalogued as rs1267127566; called by mutect2, pindel, varscan2
- ZNF214 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as rs531102831; called by muse, mutect2, varscan2
- ANKUB1 | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ARSF | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 59/152 reads (39%) | called by muse, mutect2, varscan2
- ATF6 | c.1319+1G>C p.X440_splice | Splice Site (SNP) | VAF 40/170 reads (24%) | called by muse, mutect2, varscan2
- ATRX | c.7346C>G p.S2449C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CIZ1 | c.1203G>T p.K401N | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCTN4 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- DLG1 | c.1394G>C p.R465T | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAT1 | c.7387C>G p.L2463V | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FAT1 | c.2795A>C p.Y932S | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- HMCN1 | c.13132A>G p.T4378A | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-70D | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.283); called by muse, varscan2
- IGLV3-1 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 46/135 reads (34%) | called by muse, varscan2
- IQCE | c.2062C>G p.L688V | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2
- JHY | c.880A>G p.R294G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK10 | c.475T>C p.F159L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF18B | c.1042G>C p.A348P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF27 | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LZTFL1 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MED12L | c.2289del p.V765Lfs*37 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | called by mutect2, pindel, varscan2
- MMRN2 | c.1863G>T p.E621D | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO9A | c.4004G>C p.S1335T | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NKX2-5 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NT5C2 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2
- PAX3 | c.881_892del p.F294_A298delinsS | In Frame Del (DEL) | VAF 39/155 reads (25%) | called by mutect2, pindel, varscan2
- PBX1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PKD2L2 | c.590A>T p.N197I | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SDF2 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRIM32 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIM59 | c.835C>G p.P279A | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF460 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF808 | c.463del p.Q155Sfs*59 | Frame Shift Del (DEL) | VAF 75/234 reads (32%) | called by mutect2, pindel, varscan2
- CFAP126 | c.63C>T p.N21= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as rs918538308; called by muse, mutect2, varscan2
- DEF8 | c.105C>T p.L35= | Silent (SNP) | VAF 75/211 reads (36%) | catalogued as rs750808131, COSV51919502; called by muse, mutect2, varscan2
- GPR32 | c.516G>A p.L172= | Silent (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- H2AC20 | c.256C>T p.L86= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs782404305; called by muse, mutect2, varscan2
- MUC17 | c.5133A>C p.S1711= | Silent (SNP) | VAF 88/389 reads (23%) | called by muse, mutect2, varscan2
- NABP1 | c.117C>A p.G39= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- PRG2 | c.435C>T p.I145= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- SEL1L2 | c.1056G>A p.P352= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as rs773756757, COSV53149775, COSV53158088; called by muse, mutect2, varscan2
- ABCB5 | c.*234A>G | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- AC104472.1 | n.510G>T | RNA (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- AGMO | c.*435G>C | 3'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- ALAD | c.*422G>T | 3'UTR (SNP) | VAF 36/252 reads (14%) | catalogued as rs41276805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANAPC1 | c.*548G>A | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- BCL11B | c.*58_*61dup | 3'UTR (INS) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- BMP6 | c.*1193_*1211del | 3'UTR (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- CDH2 | c.2514+68C>A | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, varscan2
- CHMP1A | c.7+38G>A | Intron (SNP) | VAF 15/100 reads (15%) | catalogued as rs764222059; called by muse, mutect2, varscan2
- CNOT11 | c.-33C>G | 5'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- DNAJC16 | c.*1455T>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs1294943642; called by mutect2, varscan2
- DTX1 | c.-230A>T | 5'UTR (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- ENPEP | c.*916T>C | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- EPHA8 | c.*805C>T | 3'UTR (SNP) | VAF 38/159 reads (24%) | catalogued as rs796805534; called by muse, mutect2, varscan2
- ETNK1 | c.-209C>T | 5'UTR (SNP) | VAF 19/96 reads (20%) | catalogued as rs756513365; called by muse, mutect2, varscan2
- EVPLL | c.-10C>G | 5'UTR (SNP) | VAF 18/201 reads (9%) | called by muse, mutect2
- FAM135B | c.*1741T>G | 3'UTR (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2
- FCGR3A | c.*1198T>C | 3'UTR (SNP) | VAF 84/300 reads (28%) | called by muse, mutect2, varscan2
- FSD1L | c.1026-9544C>T | Intron (SNP) | VAF 13/153 reads (8%) | called by muse, mutect2
- GP2 | c.-56G>A | 5'UTR (SNP) | VAF 21/82 reads (26%) | catalogued as rs1472587717; called by muse, mutect2, varscan2
- IL20RA | c.*1009T>C | 3'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- INTU | c.1181+1773T>C | Intron (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- IQCH | c.*906T>C | 3'UTR (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- KLHL23 | c.*266T>C | 3'UTR (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- MAGT1 | chrX:77895486 C>T | 5'Flank (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- MAP3K13 | c.*894T>C | 3'UTR (SNP) | VAF 58/130 reads (45%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851317 G>A | 5'Flank (SNP) | VAF 62/192 reads (32%) | catalogued as rs766572654; called by muse, mutect2, varscan2
- MORN4 | c.*66G>T | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- NEDD4 | c.*938T>A | 3'UTR (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- NFIB | c.*5086G>C | 3'UTR (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- NGDN | chr14:23478728 del ACCCCC | 3'Flank (DEL) | VAF 4/28 reads (14%) | catalogued as rs1358561098; called by pindel, varscan2*
- NGEF | c.*201A>G | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- OR4C49P | n.363C>T | RNA (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- PAPPA | c.*998G>T | 3'UTR (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- PAX5 | c.910+13G>A | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as rs749491561; called by muse, mutect2, varscan2
- PSMA2 | c.374+21G>C | Intron (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2
- PSMG3-AS1 | n.3435G>A | RNA (SNP) | VAF 6/39 reads (15%) | catalogued as rs1562580598; called by muse, mutect2, varscan2
- RBM25 | c.*409A>T | 3'UTR (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- RNASEH1 | c.128+376T>G | Intron (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- SHANK2 | c.*2239T>C | 3'UTR (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- SLC16A14 | c.*2094G>A | 3'UTR (SNP) | VAF 19/62 reads (31%) | catalogued as rs142812557; called by muse, mutect2, varscan2
- SLC30A4 | c.*3175T>G | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- SP110 | c.1815+352del | Intron (DEL) | VAF 53/212 reads (25%) | called by mutect2, pindel, varscan2
- SPRED2 | c.27-21756G>C | Intron (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- TAFA1 | c.-3-220T>A | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- TCN2 | c.-114C>T | 5'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- TMPRSS11A | c.-616C>G | 5'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- TNS1 | c.*4372A>T | 3'UTR (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- UNC5C | c.*2102C>A | 3'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- ZFYVE21 | c.-1C>T | 5'UTR (SNP) | VAF 7/24 reads (29%) | catalogued as rs552342705; called by muse, mutect2, varscan2
